Somatic mutation profile of tumor specimen TCGA-IC-A6RE-01A (aliquot TCGA-IC-A6RE-01A-11D-A33E-09) from TCGA case TCGA-IC-A6RE, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 59.2 years (21,640 days).
Specimen TCGA-IC-A6RE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa97748b-556e-4b1f-846f-84b4aff618ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IC-A6RE-10A (Blood Derived Normal), aliquot TCGA-IC-A6RE-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78c5d451-34f2-4a65-8212-c895678a9cc5

The open-access MAF lists 460 somatic variants for this specimen: 355 protein-altering or splice-affecting, 92 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 326, Silent 92, Nonsense Mutation 16, Frame Shift Del 6, RNA 6, Splice Site 3, Intron 3, In Frame Del 2, Translation Start Site 2, 5'Flank 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55876538, COSV55894288; called by muse, mutect2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 12/110 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 18/25 reads (72%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACHE | c.1306C>T p.H436Y | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.194); catalogued as COSV99574505; called by muse, mutect2
- ACP2 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1015461061, COSV57042592; called by muse, mutect2, varscan2
- AEBP1 | c.761A>G p.K254R | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV56260884; called by muse, mutect2
- AKAP3 | c.1205A>C p.E402A | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs772438163; called by muse, mutect2, varscan2
- ALS2CL | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs139526721, COSV100014848; called by muse, mutect2, varscan2
- AMELX | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs367556910, COSV61631109; called by muse, mutect2, varscan2
- AMY1C | c.884G>A p.W295* | Nonsense Mutation (SNP) | VAF 14/282 reads (5%) | catalogued as rs899245319; called by muse, mutect2
- ARHGAP20 | c.601T>C p.F201L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.815); catalogued as COSV99505587; called by muse, mutect2, varscan2
- ARHGAP28 | c.1307T>G p.L436R (on ENST00000383472 / NM_001366230.1; = p.L277R on NM_001010000.3) | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51632708, COSV51641871; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1996G>C p.G666R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV57748303; called by muse, mutect2, varscan2
- ATRX | c.7141G>A p.E2381K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1557041077; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C21orf91 | c.600_602del p.E201del | In Frame Del (DEL) | VAF 11/44 reads (25%) | catalogued as rs771502455; called by pindel, varscan2
- CACNA1F | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs1557111435; called by muse, mutect2, varscan2
- CCNJL | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs908098830; called by muse, mutect2, varscan2
- CDH11 | c.1462T>G p.F488V | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.265); catalogued as COSV51773337; called by muse, mutect2
- CNTLN | c.1262A>C p.K421T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV52099592; called by muse, mutect2, varscan2
- CNTNAP2 | c.2368C>T p.R790C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs200089329, COSV100665013; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.3801T>A p.D1267E | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV62019411; called by muse, mutect2, varscan2
- CORO7 | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746084994; called by muse, mutect2, varscan2
- CRNKL1 | c.1880A>C p.K627T | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as rs1331459406; called by muse, mutect2
- CSMD3 | c.107A>C p.K36T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); catalogued as COSV52147684; called by muse, mutect2, varscan2
- CUBN | c.149A>C p.N50T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV64702239; called by muse, mutect2, varscan2
- CYP8B1 | c.1255T>C p.F419L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762454550; called by muse, mutect2, varscan2
- DIP2B | c.4609G>A p.V1537M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs747159501; called by muse, mutect2, varscan2
- DMBT1 | c.6080G>A p.R2027H (on ENST00000338354 / NM_001377530.1; = p.R1270H on NM_004406.3) | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768251433, COSV57557328; called by muse, mutect2, varscan2
- DNAH5 | c.9767A>C p.K3256T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV54218741; called by muse, mutect2, varscan2
- DNAH9 | c.530T>A p.L177H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.212); catalogued as COSV52332564; called by muse, mutect2, varscan2
- DPP10 | c.951A>C p.R317S | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.656); catalogued as COSV59674985; called by muse, mutect2, varscan2
- DYNC2H1 | c.5180T>C p.I1727T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1478814855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFCAB6 | c.3623G>A p.R1208H | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs144440757; called by muse, mutect2, varscan2
- EPPK1 | c.5258G>A p.G1753D | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73261395; called by muse, mutect2, varscan2
- ERBB4 | c.1346C>A p.S449Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53506506; called by muse, mutect2, varscan2
- ERMARD | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.761); catalogued as rs769372457; called by muse, mutect2, varscan2
- FIGN | c.732T>G p.S244R | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.044); catalogued as COSV60764012; called by muse, mutect2, varscan2
- FLG | c.3643A>C p.S1215R | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV100910503, COSV64238953, COSV64251096; called by muse, mutect2, varscan2
- GABRA1 | c.429C>A p.N143K | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV50107615; called by muse, mutect2, varscan2
- GFRA3 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs573286530; called by muse, mutect2, varscan2
- GNAI3 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV63983679; called by muse, mutect2, varscan2
- GPR34 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1169636234, COSV59371515; called by muse, mutect2, varscan2
- GRIA4 | c.1684T>G p.L562V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99228309; called by muse, mutect2, varscan2
- HFM1 | c.2087T>G p.L696R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99646355; called by mutect2, varscan2
- HJV | c.653G>A p.R218Q (on ENST00000336751 / NM_213653.4; = p.R105Q on NM_145277.5) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV60952572; called by muse, mutect2, varscan2
- HMCN1 | c.5533G>A p.A1845T | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770829339, COSV54889918; called by muse, mutect2, varscan2
- HYOU1 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375666355; called by muse, mutect2, varscan2
- IGSF1 | c.826A>C p.K276Q | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.35); PolyPhen benign (0.305); catalogued as COSV100811787; called by muse, mutect2, varscan2
- IL1RL1 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs765548823; called by muse, mutect2, varscan2
- KCNH7 | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs1195986422, COSV59815183; called by muse, mutect2
- KIAA1755 | c.683T>A p.L228H | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.72); catalogued as rs1555826905; called by muse, mutect2, varscan2
- KIF9 | c.1290-1G>A p.X430_splice | Splice Site (SNP) | VAF 5/46 reads (11%) | catalogued as rs1210371891; called by muse, mutect2, varscan2
- KRIT1 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs527290163; called by muse, mutect2
- LAMB4 | c.3715G>C p.G1239R | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.331); catalogued as COSV52720788; called by muse, mutect2, varscan2
- LRTM1 | c.1005A>C p.E335D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99836206; called by muse, mutect2
- LUM | c.634T>G p.L212V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs749360955, COSV57127364, COSV57129189; called by muse, mutect2, varscan2
- MAGEA8 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs929885088, COSV54063682; called by muse, mutect2, varscan2
- MCF2L2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs773032244, COSV61055281; called by muse, mutect2, varscan2
- MS4A14 | c.1013A>C p.K338T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1488946974, COSV100280777; called by muse, mutect2
- MYH7 | c.4760A>C p.K1587T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV62520210; called by muse, mutect2, varscan2
- NBAS | c.1333A>T p.S445C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as rs751468811; called by muse, mutect2, varscan2
- NCKAP1L | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764565874, COSV53203168; called by muse, varscan2
- NEO1 | c.3016G>A p.V1006I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.318); catalogued as rs1301764901; called by muse, mutect2, varscan2
- NKX3-2 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as rs772588647, COSV101220027; called by muse, mutect2, varscan2
- NUP98 | c.2045A>G p.N682S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs751965989; called by muse, mutect2, varscan2
- OR10J3 | c.74A>G p.K25R | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs751749308; called by muse, mutect2, varscan2
- OR2K2 | c.340T>G p.L114V (on ENST00000374428; = p.L85V on NM_205859.2) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.22); catalogued as rs781486724, COSV57018398; called by muse, mutect2, varscan2
- OR2T4 | c.719T>A p.L240H | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63544465, COSV63544829; called by muse, mutect2, varscan2
- OR8H3 | c.481G>C p.V161L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1454761977; called by muse, mutect2
- OR8J1 | c.613A>C p.T205P | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV57316662, COSV57318601; called by muse, mutect2, varscan2
- PAN3 | c.1496A>C p.N499T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV99145292; called by muse, mutect2, varscan2
- PAQR5 | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1406605434, COSV61818383; called by muse, mutect2, varscan2
- PCDHB8 | c.1612G>A p.G538S | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50760973; called by muse, mutect2, varscan2
- PCLO | c.12055A>G p.S4019G | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV100434242; called by muse, mutect2, varscan2
- PDZRN3 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99071901; called by muse, mutect2, varscan2
- POLA2 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767341756; called by muse, mutect2, varscan2
- POLR3H | c.14T>G p.V5G | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV61749529; called by muse, mutect2
- POU4F3 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as rs912845369; called by muse, mutect2, varscan2
- PRAMEF6 | c.377T>G p.L126R | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.125); catalogued as COSV61910049; called by muse, mutect2, varscan2
- PRAMEF7 | c.1063T>A p.L355I | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100435040; called by muse, mutect2, varscan2
- PRRC2C | c.5102G>T p.R1701L (on ENST00000367742; = p.R1699L on NM_015172.4) | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100144581, COSV58908159; called by muse, mutect2, varscan2
- RGL4 | c.943G>T p.V315L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.195); catalogued as COSV51944951; called by muse, mutect2, varscan2
- RMI1 | c.1839G>A p.M613I | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57936045; called by muse, mutect2
- RNF17 | c.3041T>G p.L1014R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55041011; called by muse, mutect2, varscan2
- ROBO4 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.869); catalogued as rs986434452; called by muse, mutect2, varscan2
- RPL13A | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as rs569616137, COSV99201261; called by muse, mutect2, varscan2
- RTF1 | c.1908G>C p.M636I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV101047509; called by mutect2, varscan2
- RYR2 | c.6481C>A p.L2161I | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63679056; called by muse, mutect2, varscan2
- SAMM50 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV63110187; called by muse, mutect2, varscan2
- SENP7 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV58620934; called by muse, mutect2, varscan2
- SGIP1 | c.1657A>G p.T553A | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV52772511; called by muse, mutect2, varscan2
- SIPA1L2 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV53384632; called by muse, mutect2, varscan2
- SLC45A4 | c.2145C>G p.I715M (on ENST00000517878 / NM_001286646.2; = p.I664M on NM_001080431.2) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1336703080; called by muse, mutect2, varscan2
- SLCO1B3 | c.103T>A p.S35T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV53937143; called by muse, mutect2, varscan2
- SPEG | c.8968C>T p.R2990* | Nonsense Mutation (SNP) | VAF 29/47 reads (62%) | catalogued as rs1433405348; called by muse, mutect2, varscan2
- STT3A | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.086); catalogued as COSV67065171; called by muse, varscan2
- STX18 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV60373296; called by muse, mutect2, varscan2
- TBX22 | c.1372T>C p.S458P | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1288986462, COSV100960719; called by muse, mutect2, varscan2
- TBX5 | c.490C>G p.H164D | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV59865030; called by muse, mutect2, varscan2
- TET1 | c.5264G>C p.G1755A | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.243); catalogued as COSV65387596; called by muse, mutect2, varscan2
- TET1 | c.5645C>T p.T1882M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs759636615; called by muse, mutect2, varscan2
- TIGD3 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs142471374; called by muse, mutect2, varscan2
- TRPC7 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs571109629, COSV61452442; called by muse, varscan2
- TRPS1 | c.3361G>A p.V1121I (on ENST00000220888 / NM_001330599.2; = p.V1134I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as rs143500511; called by muse, mutect2, varscan2
- TTN | c.66711A>C p.K22237N (on ENST00000591111; = p.K14813N on NM_003319.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | PolyPhen probably damaging (0.997); catalogued as COSV59921314; called by mutect2, varscan2
- UBQLNL | c.302A>C p.K101T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100974223, COSV66492601; called by muse, mutect2, varscan2
- USH2A | c.3658G>C p.V1220L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.047); catalogued as COSV100227773; called by muse, mutect2, varscan2
- WWC3 | c.2166G>C p.W722C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66505574; called by muse, mutect2, varscan2
- XRRA1 | c.596T>G p.L199R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1322602515; called by muse, mutect2, varscan2
- ZBED9 | c.3332T>G p.I1111S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as COSV71729125; called by mutect2, varscan2
- ZBTB7B | c.236C>T p.T79M (on ENST00000292176; = p.T113M on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs753049116; called by muse, mutect2, varscan2
- ZFPM2 | c.2530A>G p.T844A | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV65873459; called by muse, mutect2, varscan2
- ZNF234 | c.1519A>C p.T507P | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256954324; called by muse, mutect2, varscan2
- ZNF408 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV100305606; called by muse, mutect2, varscan2
- ZNF600 | c.1109A>T p.K370M | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs758713877; called by muse, mutect2
- ZNF662 | c.1073A>G p.K358R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs751718984; called by muse, mutect2, varscan2
- ZNF804B | c.2063T>C p.V688A | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs767498932, COSV60844915; called by muse, mutect2, varscan2
- ZNF85 | c.1418A>C p.K473T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV100060236; called by muse, mutect2, varscan2
- ABCA6 | c.858A>G p.I286M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ABHD6 | c.872A>C p.K291T | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ACAP2 | c.388del p.V130Sfs*9 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- ACSM2B | c.554A>C p.E185A | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ACTL7A | c.986A>T p.K329M | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ADAMTS14 | c.2938-1G>C p.X980_splice | Splice Site (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- ADAMTS6 | c.3307C>G p.R1103G | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRE3 | c.1202T>A p.L401Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKNA | c.3828A>T p.Q1276H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- AL592490.1 | c.1359T>G p.F453L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ALPK3 | c.2690T>C p.F897S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANK3 | c.10267G>A p.E3423K | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ANKRD2 | c.695T>A p.L232H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANLN | c.1406G>A p.C469Y | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- APBB1IP | c.617A>G p.N206S | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- APC | c.2713A>C p.S905R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- APP | c.1421A>G p.E474G | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ARV1 | c.275T>G p.L92R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ASPM | c.8977G>A p.E2993K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ATP12A | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AXDND1 | c.1124A>C p.Y375S | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BCAR1 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- BCKDHA | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- BCL11B | c.2512A>T p.K838* (on ENST00000357195 / NM_001282237.2; = p.K767* on NM_022898.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- BMP10 | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- BPIFC | c.490C>G p.Q164E | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- C1orf94 | c.636T>A p.C212* (on ENST00000488417 / NM_001134734.2; = p.C22* on NM_032884.5) | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- CAMK2B | c.1120C>A p.P374T | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CBL | c.904C>G p.Q302E | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCDC7 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- CCDC89 | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- CCDC93 | c.1699G>T p.V567L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CDC45 | c.1109A>T p.K370M | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CDK12 | c.2458T>A p.L820I | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CELSR2 | c.7533_7535del p.C2511del | In Frame Del (DEL) | VAF 8/30 reads (27%) | called by pindel, varscan2
- CHP2 | c.557T>G p.V186G | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- CHSY3 | c.1589del p.N530Tfs*24 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | called by mutect2, pindel, varscan2
- CLEC2B | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- CMAS | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- CNNM2 | c.1814A>G p.D605G | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CP | c.2657T>G p.V886G | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- CRISP3 | c.703A>T p.T235S (on ENST00000371159 / NM_001368123.1; = p.T217S on NM_006061.4) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.117); called by muse, mutect2
- CSMD2 | c.8629G>C p.A2877P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CTSH | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCSTAMP | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- DEFB124 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- DENND4B | c.1217G>A p.G406D | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DGKB | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.889); called by muse, mutect2
- DHODH | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2
- DLD | c.229G>T p.G77C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DMD | c.6094T>G p.F2032V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNAH7 | c.3114A>T p.R1038S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DOCK3 | c.514T>A p.S172T | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DPY19L1 | c.1022T>G p.V341G | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2
- DST | c.12619A>G p.I4207V (on ENST00000361203 / NM_001374722.1; = p.I1795V on NM_015548.5) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- DYNC2H1 | c.5609A>C p.K1870T | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC2H1 | c.9197T>G p.L3066R | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ELK1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHB1 | c.2095T>G p.F699V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EVA1A | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 24/49 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAF1 | c.1424A>T p.E475V | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- FAM160A2 | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- FAM81A | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.318); called by mutect2, varscan2
- FANCM | c.1498C>T p.Q500* | Nonsense Mutation (SNP) | VAF 21/96 reads (22%) | called by muse, mutect2, varscan2
- FAT1 | c.6666C>G p.D2222E | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FAT3 | c.10244T>G p.L3415R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- FBXO15 | c.1502A>T p.K501I | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FEM1B | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FLG | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- FLG2 | c.584A>G p.D195G | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FNDC1 | c.4271A>C p.K1424T | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- FOXG1 | c.533A>C p.K178T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FPGT | c.1343T>G p.I448S | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- FSCB | c.1319T>G p.L440R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FSTL5 | c.581T>C p.L194P | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- G3BP2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GABRB3 | c.767T>A p.L256Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GDPD1 | c.637T>G p.F213V | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- GLMN | c.1240T>A p.S414T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- GPR55 | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GRID2 | c.1385G>A p.G462D | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GUCA1C | c.523T>G p.F175V | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- H2BC10 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HDGFL3 | c.284A>C p.K95T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- HDLBP | c.1879A>T p.I627F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- HEATR5B | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- HECTD4 | c.5864A>G p.K1955R | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HERC1 | c.4411C>T p.Q1471* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- HORMAD1 | c.23G>C p.R8T | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- HOXB2 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGSF10 | c.2291A>C p.K764T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- INCENP | c.206G>A p.R69K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INPP5F | c.1005C>A p.S335R | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- ISLR | c.613C>A p.Q205K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.018); called by muse, varscan2
- ITSN1 | c.3026C>T p.A1009V | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ITSN1 | c.3673T>A p.L1225I | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2
- JAK3 | c.2875A>C p.S959R | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.438); called by muse, mutect2
- KATNAL2 | c.485A>C p.N162T (on ENST00000356157 / NM_001353899.1; = p.N90T on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2
- KCNS3 | c.586C>A p.L196M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- KDM3B | c.2066A>C p.K689T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- KIAA0895 | c.1229G>T p.R410M (on ENST00000297063 / NM_001100425.2; = p.R359M on NM_015314.3) | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2
- KIAA1109 | c.7484G>A p.R2495K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT24 | c.470A>C p.K157T | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- KRT26 | c.82T>G p.F28V | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.19); called by muse, mutect2
- KRT84 | c.749A>T p.K250M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KRT85 | c.1168G>T p.G390C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by mutect2, varscan2
- L3MBTL4 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- LIMCH1 | c.1876C>T p.L626F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- LIPI | c.1242C>G p.D414E | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- LRRC30 | c.640T>A p.F214I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LRRC8A | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.015); called by muse, mutect2
- LZTR1 | c.1102G>C p.D368H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MAGEA4 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEL2 | c.3200A>G p.N1067S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MCM4 | c.1295T>G p.L432R | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MED14 | c.3317C>T p.A1106V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEI1 | c.3263C>A p.A1088D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- MMS19 | c.1520T>A p.L507Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MOXD1 | c.1742G>T p.C581F | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2
- MPDZ | c.1020A>C p.E340D | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- MROH6 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 76/132 reads (58%) | called by muse, mutect2, varscan2
- MSH4 | c.1006T>C p.F336L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.057); called by muse, mutect2
- MUC16 | c.13499del p.S4500Tfs*5 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | called by mutect2, pindel, varscan2
- MUC16 | c.12317G>C p.S4106T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MXRA5 | c.3509del p.P1170Hfs*79 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by muse*, pindel
- MYBPC3 | c.1322A>G p.E441G | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- MYH1 | c.4703A>C p.E1568A | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- MYO3A | c.3574del p.M1192* | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | called by mutect2, varscan2
- NAV2 | c.2735T>G p.L912R (on ENST00000396087 / NM_001244963.2; = p.L889R on NM_145117.5) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NEO1 | c.3430T>A p.S1144T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- NEUROD4 | c.10A>C p.T4P | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- NME8 | c.65A>T p.E22V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- NOP16 | c.276T>A p.Y92* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- NRXN1 | c.1538C>G p.P513R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2
- NSA2 | c.227A>G p.K76R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NUP210 | c.5026T>G p.F1676V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OLFM1 | c.992T>A p.L331H (on ENST00000371793 / NM_001282611.2; = p.L313H on NM_014279.5) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- OR2J3 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.105); called by muse, mutect2
- OR2M2 | c.780A>G p.I260M | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2Z1 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4S2 | c.526T>A p.F176I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR52K1 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PARP8 | c.1568T>G p.M523R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by mutect2, varscan2
- PCDHA13 | c.2257C>G p.Q753E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCNX1 | c.254T>G p.L85R | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDZD2 | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PELP1 | c.1235G>A p.G412D | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.132); called by muse, mutect2
- PGLYRP2 | c.1028T>C p.L343P | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PKDREJ | c.2584T>C p.Y862H | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- PKP4 | c.3512T>C p.F1171S | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- PLEKHM3 | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0); called by mutect2, varscan2
- PLPPR4 | c.1444A>G p.S482G | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLRG1 | c.1046G>T p.S349I | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLB | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- POLD2 | c.860G>A p.S287N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); called by muse, varscan2
- POLR3B | c.3254T>C p.L1085P | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- POLR3H | c.13G>T p.V5L | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- PRAMEF1 | c.1278T>A p.N426K | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PRAMEF20 | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PRB4 | c.570A>C p.E190D | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRDM11 | c.585G>T p.W195C (on ENST00000530656 / NM_001359633.1; = p.W161C on NM_001256695.1) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKD1 | c.1098A>C p.Q366H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRMT9 | c.1709G>C p.G570A | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRPF6 | c.2489G>T p.S830I | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRRG2 | c.530C>T p.T177I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PSG7 | c.791C>G p.P264R | Missense Mutation (SNP) | VAF 60/272 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PSMA7 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN21 | c.1356G>C p.E452D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTPN23 | c.3507G>C p.E1169D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- PTPRD | c.2459C>T p.T820I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PTPRD | c.1088C>G p.S363C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PXYLP1 | c.1094A>G p.E365G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB5A | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- RDH10 | c.448T>C p.S150P | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- REL | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- RELB | c.945C>A p.C315* | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
- RFC5 | c.461T>C p.I154T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RFWD3 | c.1222A>G p.S408G | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- RMI1 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- RNF20 | c.1804A>T p.K602* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- RPS14 | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- RSPO2 | c.89A>G p.K30R | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.981); called by muse, mutect2
- RUNDC3B | c.157T>C p.F53L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RYR3 | c.10702A>G p.S3568G (on ENST00000389232; = p.S3569G on NM_001036.6) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- SAMD9L | c.770A>C p.K257T | Missense Mutation (SNP) | VAF 23/504 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.184); called by muse, mutect2
- SCN5A | c.5866T>G p.F1956V (on ENST00000333535 / NM_198056.3; = p.F1955V on NM_000335.5) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- SETX | c.2438A>G p.E813G | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SH2D3C | c.1202C>A p.P401Q (on ENST00000314830 / NM_170600.3; = p.P244Q on NM_005489.4) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC25A19 | c.370T>C p.C124R | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC35D1 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- SLC6A15 | c.973A>C p.K325Q | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); called by muse, mutect2
- SLC7A11 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC9C1 | c.676A>C p.S226R | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.69); called by muse, mutect2
- SMARCA4 | c.3632A>C p.E1211A | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- SNRNP48 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SOBP | c.1040C>T p.T347M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOCS4 | c.502C>G p.Q168E | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORCS3 | c.2157A>C p.K719N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- SPNS3 | c.861G>T p.E287D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- SPPL3 | c.310G>T p.V104F | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- SPTA1 | c.3748A>G p.S1250G | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- SPTY2D1 | c.554A>T p.E185V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- STAG3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 7/185 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- STK36 | c.1901T>C p.V634A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TACC2 | c.4525T>G p.L1509V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- TAS2R30 | c.754T>A p.F252I | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- TAS2R46 | c.209A>C p.E70A | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TBC1D9 | c.1643A>T p.K548M | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2
- TENM1 | c.2864G>C p.W955S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- TESPA1 | c.644T>C p.L215P (on ENST00000316577 / NM_001098815.3; = p.L77P on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- TEX11 | c.1185T>G p.I395M (on ENST00000344304; = p.I380M on NM_031276.3) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TIAM1 | c.3941T>G p.L1314R | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- TJP1 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TMEM86B | c.609G>C p.M203I | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNFAIP1 | c.263G>C p.R88P | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNK2 | c.2948G>T p.G983V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TRAF4 | c.43C>G p.R15G | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- TRERF1 | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- TRHDE | c.2936A>T p.K979M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TRIB3 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRMT11 | c.805A>C p.N269H | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTC21B | c.1472T>C p.L491P | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.10630del p.T3544Pfs*17 (on ENST00000591111; = p.T3498Pfs*17 on NM_003319.4) | Frame Shift Del (DEL) | VAF 23/51 reads (45%) | called by mutect2, pindel, varscan2
- TTN | c.1398+1G>A p.X466_splice | Splice Site (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- TUBA3C | c.505T>G p.F169V | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.415); called by muse, mutect2
- UBAC2 | c.524C>G p.S175C (on ENST00000403766 / NM_001144072.2; = p.S140C on NM_177967.4) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- UGT3A2 | c.298A>T p.T100S | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- VAV2 | c.931G>A p.V311I (on ENST00000371850 / NM_001134398.2; = p.V306I on NM_003371.4) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- VPS13D | c.12903A>T p.E4301D | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- WDR11 | c.2664A>T p.Q888H | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZFP42 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- ZNF565 | c.846G>T p.Q282H (on ENST00000355114; = p.Q242H on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF572 | c.626C>A p.T209N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ZNF681 | c.340A>C p.S114R | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF813 | c.926G>C p.S309T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- ZNF880 | c.829T>C p.F277L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF99 | c.197A>C p.K66T | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ADAMTS18 | c.2499G>A p.A833= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs538095477, COSV51415536, COSV99271901; called by muse, mutect2, varscan2
- ADGRV1 | c.3516T>G p.T1172= | Silent (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- AFTPH | c.2268A>G p.G756= | Silent (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- ARHGAP36 | c.723T>A p.A241= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as COSV52270709; called by muse, mutect2, varscan2
- ASH1L | c.3741A>G p.K1247= | Silent (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- ASPA | c.726C>A p.I242= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV53979779; called by muse, mutect2, varscan2
- ATAD2 | c.4143A>G p.Q1381= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- BCAS3 | c.2118T>G p.S706= (on ENST00000390652 / NM_001353144.2; = p.S691= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- BOD1L1 | c.3336A>T p.T1112= | Silent (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- CABP1 | c.1095C>G p.V365= (on ENST00000316803 / NM_001033677.1; = p.V162= on NM_004276.5) | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs200202796; called by muse, mutect2, varscan2
- CEP85L | c.2271T>G p.A757= | Silent (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- CNPY1 | c.15G>A p.K5= | Silent (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
- COL14A1 | c.4101T>G p.T1367= | Silent (SNP) | VAF 8/117 reads (7%) | called by muse, mutect2
- CSGALNACT1 | c.411C>A p.V137= | Silent (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
- CYFIP1 | c.1119G>T p.T373= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- CYP4F22 | c.435G>A p.L145= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1412587153; called by muse, mutect2
- DCC | c.3963T>A p.S1321= | Silent (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- DEFB110 | c.90C>T p.D30= | Silent (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- EDNRA | c.159A>G p.Q53= | Silent (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- EHD4 | c.168C>T p.A56= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs1247922055; called by muse, mutect2, varscan2
- ERV3-1 | c.729T>G p.T243= | Silent (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- EYA1 | c.219T>C p.S73= | Silent (SNP) | VAF 32/48 reads (67%) | called by muse, mutect2, varscan2
- FOLH1 | c.159T>C p.T53= | Silent (SNP) | VAF 26/100 reads (26%) | called by muse, mutect2, varscan2
- FZD5 | c.771C>T p.F257= | Silent (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- GATA1 | c.1155C>G p.P385= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- GLRB | c.1233T>C p.S411= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as rs1046528704; called by muse, mutect2
- GPAA1 | c.1141T>C p.L381= | Silent (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- HIC2 | c.1557G>T p.T519= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs764115290; called by muse, mutect2, varscan2
- HMCN1 | c.11322T>C p.H3774= | Silent (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- HNRNPD | c.498G>A p.V166= | Silent (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- IBSP | c.252T>G p.T84= | Silent (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- IRGQ | c.72C>T p.I24= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV60670983, COSV60671165; called by muse, mutect2, varscan2
- ITPR1 | c.1476A>G p.Q492= (on ENST00000354582; = p.Q477= on NM_002222.7) | Silent (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- JAG2 | c.3369C>T p.S1123= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs138204105; ClinVar: benign; called by muse, varscan2
- KIF24 | c.6A>T p.A2= | Silent (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- KRT27 | c.81A>C p.G27= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- KRT4 | c.1092G>A p.R364= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- KRT76 | c.1584G>T p.G528= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- LIX1 | c.582T>C p.S194= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2
- LMOD1 | c.1059G>A p.E353= | Silent (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- LRIG1 | c.1962C>T p.D654= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs771674613; called by muse, mutect2, varscan2
- LRP12 | c.1104T>G p.T368= | Silent (SNP) | VAF 29/42 reads (69%) | called by muse, mutect2, varscan2
- LRP1B | c.759A>G p.R253= | Silent (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- LRP1B | c.375T>C p.C125= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs764566827; called by muse, mutect2, varscan2
- MECP2 | c.708G>T p.G236= | Silent (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- MELTF | c.264G>A p.E88= | Silent (SNP) | VAF 10/30 reads (33%) | called by muse, varscan2
- MFSD8 | c.39C>G p.L13= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV56553321; called by muse, mutect2
- MIDEAS | c.663C>T p.F221= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as rs749437985, COSV54094389; called by muse, mutect2, varscan2
- MMRN2 | c.18G>A p.L6= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- MUC5B | c.15141C>T p.V5047= | Silent (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- NDST3 | c.1185T>C p.S395= | Silent (SNP) | VAF 40/176 reads (23%) | called by muse, mutect2, varscan2
- NPC1 | c.3216C>T p.N1072= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs779463609, COSV52570315; called by muse, mutect2, varscan2
- OR4D6 | c.123A>G p.G41= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- PCDH15 | c.4665A>G p.K1555= | Silent (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- PCDH15 | c.1273A>C p.R425= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV100225503; called by muse, mutect2, varscan2
- PCLO | c.4707T>G p.A1569= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV61623943, COSV61631831; called by muse, mutect2, varscan2
- PIGL | c.459C>T p.G153= | Silent (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- PIWIL1 | c.762T>C p.T254= | Silent (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- PLCB1 | c.1104G>T p.R368= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100572232; called by mutect2, varscan2
- POLQ | c.7038T>G p.R2346= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- POU3F2 | c.54C>A p.I18= | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as rs773775751; called by muse, mutect2, varscan2
- PRAMEF15 | c.360A>G p.E120= | Silent (SNP) | VAF 32/206 reads (16%) | called by muse, mutect2, varscan2
- PREX2 | c.1827C>T p.D609= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV55805538; called by muse, mutect2, varscan2
- PRR16 | c.382A>C p.R128= (on ENST00000407149 / NM_001300783.2; = p.R105= on NM_016644.2) | Silent (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- RASA4 | c.354C>T p.G118= | Silent (SNP) | VAF 42/252 reads (17%) | catalogued as rs781292722; called by mutect2, varscan2
- RB1CC1 | c.2376T>G p.T792= | Silent (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- RTL9 | c.3975G>T p.L1325= | Silent (SNP) | VAF 23/30 reads (77%) | called by muse, mutect2, varscan2
- SCN11A | c.3418T>C p.L1140= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV56566210; called by muse, varscan2
- SCRN1 | c.681T>C p.S227= | Silent (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
- SET | c.474G>C p.L158= (on ENST00000372692 / NM_001374326.1; = p.L145= on NM_003011.4) | Silent (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- SGSM2 | c.1716C>T p.R572= (on ENST00000426855 / NM_001098509.2; = p.R617= on NM_014853.3) | Silent (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- SHROOM3 | c.519C>T p.P173= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs764718554; called by muse, mutect2, varscan2
- SLC12A5 | c.3138T>A p.P1046= (on ENST00000454036 / NM_001134771.2; = p.P1023= on NM_020708.5) | Silent (SNP) | VAF 42/103 reads (41%) | called by muse, mutect2, varscan2
- SLIT3 | c.3162G>T p.L1054= | Silent (SNP) | VAF 12/30 reads (40%) | called by muse, varscan2
- SOX5 | c.2136T>G p.T712= | Silent (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- SPHKAP | c.4611C>G p.L1537= | Silent (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- SRRM2 | c.6882T>G p.A2294= | Silent (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- STAG3 | c.1074A>G p.E358= | Silent (SNP) | VAF 17/335 reads (5%) | called by muse, mutect2
- TDRD7 | c.1792T>C p.L598= | Silent (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- TET1 | c.5265A>G p.G1755= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs1463090132; called by muse, mutect2, varscan2
- TIMM50 | c.576C>A p.I192= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100067987; called by muse, mutect2, varscan2
- TOP1MT | c.1287C>T p.N429= | Silent (SNP) | VAF 49/76 reads (64%) | catalogued as rs143974988, COSV61316638; called by muse, mutect2, varscan2
- TP53I13 | c.303G>A p.T101= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs779484881; called by muse, mutect2, varscan2
- TRPA1 | c.1725C>G p.V575= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs756855686; called by muse, mutect2, varscan2
- TULP4 | c.2775G>A p.L925= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV65573939; called by muse, mutect2, varscan2
- USH2A | c.7347C>A p.T2449= | Silent (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- USP46 | c.645C>T p.F215= | Silent (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- VWF | c.8238T>C p.D2746= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV54615369; called by muse, mutect2, varscan2
- ZBTB4 | c.444C>T p.L148= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs146654674; called by muse, mutect2, varscan2
- ZNF410 | c.795G>A p.R265= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs375182218; called by muse, mutect2, varscan2
- ZNF615 | c.198T>C p.T66= | Silent (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- ZNF616 | c.324T>C p.D108= | Silent (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- ABHD14A | chr3:51971641 G>A | 5'Flank (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- C15orf54 | n.543A>G | RNA (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- EPB41L3 | chr18:5630575 C>T | 5'Flank (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- GRK5 | c.148+7198A>G | Intron (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- LINC02145 | n.343G>A | RNA (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- MIR124-1 | n.73A>C | RNA (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- MIR1270 | chr19:20397459 T>G | 3'Flank (SNP) | VAF 54/196 reads (28%) | called by muse, mutect2, varscan2
- MIR516A1 | n.3T>C | RNA (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- PARD3 | c.3074+4749G>A | Intron (SNP) | VAF 12/100 reads (12%) | called by muse, varscan2
- PKD1L2 | n.2996G>A | RNA (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- SNORD116-29 | n.27A>G | RNA (SNP) | VAF 13/61 reads (21%) | catalogued as rs1163677393; called by muse, mutect2, varscan2
- WNK1 | c.2140-2671T>C | Intron (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- YIF1B | c.*1091G>C | 3'UTR (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
